Gene-level copy-number profile of tumor specimen TCGA-D6-A6EP-01A from TCGA case TCGA-D6-A6EP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.1 years (22,674 days).
Specimen TCGA-D6-A6EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.229bfb02-faf3-465c-a2c0-34634729ec2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A6EP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/46c91561-e96a-4885-82be-4026543e50f2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 144; copy number 2: 9,264; copy number 3: 20,307; copy number 4: 14,351; copy number 5: 7,567; copy number 6: 4,450; copy number 7: 1,582; copy number 8: 1,316; copy number 9: 685; copy number 10: 40; copy number 11: 37; copy number 12: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A6EP-01A-11D-A31K-01): tumor purity 0.83, ploidy 3.72, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,272,309–11,557,665, 1 gene (within-gene range 0–2): ATG7.
- chr3:11,488,300–11,529,755, 2 genes: AC026185.1, AC022001.1.
- chr4:107,590,276–107,720,234, 1 gene (within-gene range 0–2): PAPSS1.
- chr8:4,633,065–4,788,584, 2 genes: AC022068.1, PAICSP4.
- chr9:21,638,285–24,088,051, 34 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr12:48,995,149–49,110,900, 10 genes: DDN, AC011603.3, DDN-AS1, PRKAG1, KMT2D, RHEBL1, AC011603.4, DHH, AC011603.1, LMBR1L.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,653 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–156,385,219, 605 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr2:88,765,807–103,623,830, 354 genes, copy number 7 (broad region; genes not listed).
- chr2:114,442,299–117,027,024, 14 genes, copy number 7 (within-gene range 6–7): DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43.
- chr2:121,902,501–127,033,948, 34 genes, copy number 7 (within-gene range 6–7): AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2, AC023347.1, SLC6A14P3, YWHAZP2, AC013474.2, GYPC, AC013474.1, RNU6-675P, TEX51, RNU7-182P, AC012508.2, AC012508.3, AC012508.1.
- chr7:70,972–6,753,862, 164 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr7:14,145,049–37,586,329, 407 genes, copy number 7–12 (within-gene range 3–17) (broad region; genes not listed).
- chr7:46,634,614–46,759,851, 2 genes, copy number 7 (within-gene range 4–7): HMGN1P19, AC011294.1.
- chr11:32,602,246–38,686,323, 92 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr11:44,973,770–45,367,490, 7 genes, copy number 7: LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696.
- chr11:58,497,888–60,184,666, 76 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:66,040,765–85,686,195, 541 genes, copy number 8–9 (broad region; genes not listed).
- chr11:85,852,557–107,586,903, 371 genes, copy number 8–9 (broad region; genes not listed).
- chr16:5,239,802–7,713,340, 1 gene, copy number 7 (within-gene range 6–7): RBFOX1.
- chr16:5,838,131–8,532,013, 22 genes, copy number 7: AC012175.1, AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2.
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 4–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:4,771,884–22,706,703, 734 genes, copy number 7–11 (broad region; genes not listed).
- chr17:28,256,375–29,930,276, 114 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr18:316,737–4,455,307, 87 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr19:11,721,265–12,081,565, 24 genes, copy number 7: ZNF823, AC008543.3, AC008543.2, ZNF441, AC008543.5, ZNF491, ZNF440, AC008543.4, ZNF439, AC020951.1, ZNF69, ZNF700, AC008770.2, AC008770.3, ZNF763, ZNF433-AS1, AC008770.4, RNA5SP464, ZNF433, AC008770.1, RNA5SP465, ZNF878, ZNF844, RNA5SP466.

Autosomal genes at a single copy (total copy number 1): 144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
